Somatic mutation profile of tumor specimen HCM-CSHL-0654-C26-06A (aliquot HCM-CSHL-0654-C26-06A-11D-A82H-36) from HCMI case HCM-CSHL-0654-C26, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Unknown primary site; Tumor grade: G3; Age at diagnosis: 70.6 years (25,800 days).
Specimen HCM-CSHL-0654-C26-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23b1f4f2-a4fe-4488-9088-9c0141e4a8b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0654-C26-10A (Blood Derived Normal), aliquot HCM-CSHL-0654-C26-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2f49605-2db6-4c9c-97ca-edf6f4928b6d

The open-access MAF lists 155 somatic variants for this specimen: 119 protein-altering or splice-affecting, 30 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 30, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 2, Intron 2, 5'Flank 2, Splice Site 2, 3'UTR 1, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 367/426 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACIN1 | c.4010G>A p.R1337Q | Missense Mutation (SNP) | VAF 158/552 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.273); catalogued as COSV52982991; called by muse, varscan2
- ACTL9 | c.1187G>T p.C396F | Missense Mutation (SNP) | VAF 286/676 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV61004765; called by muse, mutect2, varscan2
- ADGRA2 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 203/404 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs763577512, COSV59442898; called by muse, mutect2, varscan2
- ADGRD1 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 134/615 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); catalogued as rs1394144734, COSV55446523; called by muse, mutect2, varscan2
- ARHGEF7 | c.1966C>T p.R656W (on ENST00000375741 / NM_001113511.2; = p.R478W on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 154/868 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866152255, COSV54538783, COSV54548582; called by muse, varscan2
- ATP1A2 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 217/664 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs748881406; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BANF2 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 230/446 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1317561867, COSV101617993; called by muse, mutect2, varscan2
- BMPER | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 189/469 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.073); catalogued as rs746885660; called by muse, mutect2, varscan2
- BRIP1 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 206/256 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs587780235, CM1210625, COSV52004661; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCR2 | c.41A>G p.N14S | Missense Mutation (SNP) | VAF 105/319 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1283636260; called by muse, mutect2, varscan2
- CCR7 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 142/620 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.078); catalogued as rs773362430; called by muse, varscan2
- CES1 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 230/320 reads (72%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs111604615; called by muse, varscan2
- CHRD | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 134/376 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.28); catalogued as rs771365613, COSV52608775; called by muse, mutect2, varscan2
- CHRDL1 | c.327C>A p.C109* (on ENST00000372045; = p.C115* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 448/514 reads (87%) | catalogued as COSV99488868; called by muse, mutect2, varscan2
- CHRM2 | c.920C>G p.T307R | Missense Mutation (SNP) | VAF 205/432 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV100280591; called by muse, mutect2, varscan2
- COL1A2 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 34/674 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs764174111, COSV51956900; called by muse, mutect2
- CSMD3 | c.2422C>T p.R808* (on ENST00000297405 / NM_001363185.1; = p.R704* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 93/350 reads (27%) | catalogued as COSV52172375; called by muse, mutect2, varscan2
- CXCL9 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1375851280, COSV53578486; called by muse, mutect2, varscan2
- CYP11B1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 119/476 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs764251434, CM1210436, COSV52830527; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP2B6 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 186/541 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs374099483; called by muse, mutect2, varscan2
- DDR1 | c.2584C>T p.R862W (on ENST00000324771; = p.R825W on NM_001954.4) | Missense Mutation (SNP) | VAF 216/738 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757977513, COSV61326143; called by muse, varscan2
- DGKG | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 128/432 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs368444168, COSV53975826; called by muse, mutect2
- DSCAM | c.5418T>G p.S1806R | Missense Mutation (SNP) | VAF 155/481 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1396609521, COSV101261249, COSV68020569; called by muse, mutect2, varscan2
- DYNC1I1 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 125/308 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.018); catalogued as rs756345512, COSV61474207; called by muse, mutect2, varscan2
- ERBB4 | c.2227A>G p.T743A | Missense Mutation (SNP) | VAF 27/457 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs747395103, COSV53558080; called by muse, mutect2
- EVC | c.1979C>T p.T660M | Missense Mutation (SNP) | VAF 169/479 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.799); catalogued as rs550100215, COSV53828779; called by muse, mutect2, varscan2
- F8 | c.3986G>A p.R1329H | Missense Mutation (SNP) | VAF 513/573 reads (90%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs782767347, CM062655, COSV64276561; called by muse, mutect2, varscan2
- FER1L6 | c.2920G>T p.D974Y | Missense Mutation (SNP) | VAF 5750/5883 reads (98%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV67549139; called by muse, varscan2
- FMN2 | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 260/687 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs145706266, COSV60434698; called by muse, mutect2, varscan2
- FREM3 | c.3002G>T p.G1001V | Missense Mutation (SNP) | VAF 138/389 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs913177045; called by muse, mutect2, varscan2
- FRMPD4 | c.1870A>C p.S624R | Missense Mutation (SNP) | VAF 124/665 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.031); catalogued as COSV101043163; called by muse, mutect2, varscan2
- FTCD | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 151/410 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as rs761284163, COSV52428151; called by muse, mutect2, varscan2
- GPR17 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 439/851 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs746206534; called by muse, mutect2, varscan2
- HGF | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 25/450 reads (6%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.558); catalogued as COSV55949536; called by muse, mutect2
- IFFO2 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 110/425 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs566982605; called by muse, mutect2, varscan2
- IKBKB | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 276/570 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs201303042; called by muse, mutect2, varscan2
- KCNB1 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 438/823 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65570416; called by muse, mutect2, varscan2
- KCNT2 | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 81/478 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54062032; called by muse, mutect2, varscan2
- LRP1 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 203/385 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs937133751, COSV54505729; called by muse, mutect2, varscan2
- MED12 | c.3896C>T p.S1299F | Missense Mutation (SNP) | VAF 218/289 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV61336539; called by muse, mutect2, varscan2
- NF1 | c.6755T>G p.F2252C (on ENST00000358273 / NM_001042492.3; = p.F2231C on NM_000267.3) | Missense Mutation (SNP) | VAF 268/318 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as CD1512869; called by muse, varscan2
- NIPAL4 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 109/248 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs780925737, COSV57428964; called by muse, mutect2, varscan2
- OTUD6A | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 209/274 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100611112; called by muse, mutect2, varscan2
- PADI4 | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 139/425 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752032759, COSV64923993; called by muse, mutect2, varscan2
- PANX3 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 340/641 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs766598167, COSV52513815, COSV99421153; called by muse, mutect2, varscan2
- PDGFD | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 252/314 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs766800369, COSV56371243, COSV56394791; called by muse, mutect2
- PERM1 | c.1888C>T p.R630W | Missense Mutation (SNP) | VAF 265/800 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs930930835; called by muse, mutect2, varscan2
- PNPLA1 | c.319G>C p.V107L (on ENST00000394571 / NM_001374623.1; = p.V12L on NM_173676.2) | Missense Mutation (SNP) | VAF 124/391 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1488395690; called by muse, mutect2, varscan2
- PROSER2 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 559/1019 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs1034555580; called by muse, mutect2, varscan2
- PTCHD1 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 42/750 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs1480789403; called by muse, mutect2
- RASGRF1 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 70/358 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.426); catalogued as COSV69180374; called by muse, mutect2, varscan2
- SCML4 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 267/540 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); catalogued as rs773253589, COSV64637581; called by muse, mutect2, varscan2
- SCN3A | c.5648C>A p.P1883H | Missense Mutation (SNP) | VAF 76/399 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51818913; called by muse, mutect2, varscan2
- SLC25A30 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs900441795, COSV60434032; called by muse, mutect2, varscan2
- SSC5D | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 118/323 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs941672507, COSV52702986; called by muse, mutect2, varscan2
- STC2 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 178/413 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54179778; called by muse, mutect2, varscan2
- TENM2 | c.6353G>A p.R2118H (on ENST00000518659 / NM_001122679.2; = p.R1879H on NM_001080428.3) | Missense Mutation (SNP) | VAF 123/395 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs778807457, COSV101319504; called by muse, mutect2, varscan2
- TSSK1B | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 159/460 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs745469147, COSV101181041; called by muse, mutect2, varscan2
- WDPCP | c.74A>G p.Q25R | Missense Mutation (SNP) | VAF 75/471 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.328); catalogued as rs1197970797; called by muse, mutect2, varscan2
- XRCC6 | c.1637-1G>C p.X546_splice | Splice Site (SNP) | VAF 38/244 reads (16%) | catalogued as COSV63753686; called by muse, mutect2, varscan2
- ZBTB46 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 94/484 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1204910445; called by muse, mutect2, varscan2
- ZNF382 | c.1549G>C p.E517Q | Missense Mutation (SNP) | VAF 79/411 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV99498188; called by muse, mutect2, varscan2
- ADSS2 | c.473dup p.N158Kfs*30 | Frame Shift Ins (INS) | VAF 68/238 reads (29%) | called by mutect2, pindel, varscan2
- AFDN | c.106-1G>A p.X36_splice | Splice Site (SNP) | VAF 214/263 reads (81%) | called by muse, mutect2, varscan2
- AGRN | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 145/541 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- AMIGO2 | c.711C>G p.Y237* | Nonsense Mutation (SNP) | VAF 26/486 reads (5%) | called by muse, mutect2
- ANO3 | c.1173G>T p.K391N | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARID3B | c.1496_1497del p.V499Gfs*82 (on ENST00000622429 / NM_001307939.1; = p.V498Gfs*82 on NM_006465.4) | Frame Shift Del (DEL) | VAF 87/430 reads (20%) | called by pindel, varscan2
- AVP | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 190/746 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- C12orf40 | c.1917G>T p.K639N | Missense Mutation (SNP) | VAF 103/228 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHML | c.1448A>C p.E483A | Missense Mutation (SNP) | VAF 241/546 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CYP2U1 | c.142T>A p.W48R | Missense Mutation (SNP) | VAF 221/674 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- DAPK3 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 200/1038 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, varscan2
- FREM2 | c.7830T>G p.Y2610* | Nonsense Mutation (SNP) | VAF 137/571 reads (24%) | called by muse, mutect2, varscan2
- FRMPD1 | c.3520C>T p.P1174S | Missense Mutation (SNP) | VAF 147/398 reads (37%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR88 | c.1051C>A p.L351M | Missense Mutation (SNP) | VAF 216/859 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- HSF2 | c.1447G>T p.V483F | Missense Mutation (SNP) | VAF 42/530 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); called by muse, mutect2
- IL12B | c.904A>G p.K302E | Missense Mutation (SNP) | VAF 41/246 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- IRAK1BP1 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 165/678 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCTD8 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 180/517 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLKB1 | c.1795G>C p.G599R | Missense Mutation (SNP) | VAF 136/420 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP11 | c.485C>G p.P162R | Missense Mutation (SNP) | VAF 74/378 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MEGF6 | c.1690T>G p.C564G | Missense Mutation (SNP) | VAF 166/600 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC2 | c.282_300del p.G95Pfs*31 | Frame Shift Del (DEL) | VAF 234/319 reads (73%) | called by mutect2, pindel, varscan2
- NR4A3 | c.1049A>G p.Q350R | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NRG1 | c.1789G>T p.A597S (on ENST00000405005 / NM_013964.5; = p.A602S on NM_013956.5) | Missense Mutation (SNP) | VAF 134/511 reads (26%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- P4HB | c.1273A>G p.M425V | Missense Mutation (SNP) | VAF 160/731 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- PCNT | c.2505T>G p.H835Q | Missense Mutation (SNP) | VAF 56/580 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- PLEKHS1 | c.1325C>T p.T442I | Missense Mutation (SNP) | VAF 225/294 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLXNA1 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 132/352 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.232); called by muse, varscan2
- PYHIN1 | c.1256G>T p.S419I | Missense Mutation (SNP) | VAF 119/507 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- RAI1 | c.5667_5672dup p.F1890_I1891dup | In Frame Ins (INS) | VAF 132/193 reads (68%) | called by mutect2, varscan2
- RIOK3 | c.307T>A p.F103I | Missense Mutation (SNP) | VAF 67/262 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SBF1 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 33/556 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCN2A | c.1502T>A p.L501Q | Missense Mutation (SNP) | VAF 149/431 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SERPINA12 | c.862C>A p.Q288K | Missense Mutation (SNP) | VAF 34/437 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2
- SHANK3 | c.4627C>T p.R1543C | Missense Mutation (SNP) | VAF 126/691 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, varscan2
- SLC20A2 | c.1661G>A p.R554K | Missense Mutation (SNP) | VAF 123/498 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SLC27A3 | c.508dup p.C170Lfs*51 (on ENST00000271857; = p.C42Lfs*51 on NM_024330.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 326/1145 reads (28%) | called by mutect2, pindel, varscan2
- SLCO1C1 | c.476G>C p.S159T | Missense Mutation (SNP) | VAF 70/294 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- SNRPB2 | c.157T>A p.F53I | Missense Mutation (SNP) | VAF 100/470 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- STC2 | c.147T>A p.N49K | Missense Mutation (SNP) | VAF 128/414 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SYNE1 | c.11876T>C p.I3959T | Missense Mutation (SNP) | VAF 397/472 reads (84%) | SIFT tolerated (0.41); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- TFPI2 | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 243/533 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRHDE | c.833G>C p.C278S | Missense Mutation (SNP) | VAF 189/397 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM49B | c.850C>G p.Q284E | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIP11 | c.5524del p.S1842Vfs*7 | Frame Shift Del (DEL) | VAF 37/305 reads (12%) | called by mutect2, pindel, varscan2
- TRPM3 | c.2623G>A p.V875M (on ENST00000357533 / NM_001366142.2; = p.V718M on NM_020952.6) | Missense Mutation (SNP) | VAF 100/292 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TTC16 | c.856A>T p.S286C | Missense Mutation (SNP) | VAF 46/456 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2
- UBR1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 115/241 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USP53 | c.2245T>G p.L749V | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VPS33B | c.744G>C p.E248D | Missense Mutation (SNP) | VAF 81/418 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WDR48 | c.314A>C p.H105P | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- WDR62 | c.3298T>C p.S1100P | Missense Mutation (SNP) | VAF 114/626 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WWP1 | c.1259T>C p.F420S | Missense Mutation (SNP) | VAF 125/478 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- XPO7 | c.215C>G p.S72* | Nonsense Mutation (SNP) | VAF 105/331 reads (32%) | called by muse, mutect2, varscan2
- ZNF431 | c.1473A>C p.K491N | Missense Mutation (SNP) | VAF 60/291 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- ZNF845 | c.1841A>G p.K614R | Missense Mutation (SNP) | VAF 95/404 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- ABCA2 | c.5070G>A p.P1690= (on ENST00000614293; = p.P1660= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 233/787 reads (30%) | catalogued as rs768594701, COSV55800424; called by muse, mutect2, varscan2
- ADPRHL1 | c.1197C>T p.R399= | Silent (SNP) | VAF 208/1079 reads (19%) | catalogued as rs969405629; called by muse, mutect2, varscan2
- BHLHE22 | c.201G>A p.P67= | Silent (SNP) | VAF 237/827 reads (29%) | catalogued as rs531148752, COSV100417581; called by muse, mutect2, varscan2
- C1QL2 | c.582G>A p.K194= | Silent (SNP) | VAF 271/519 reads (52%) | catalogued as COSV55607482; called by muse, mutect2, varscan2
- CCDC149 | c.1467G>A p.T489= (on ENST00000635206 / NM_001330643.2; = p.T478= on NM_173463.5) | Silent (SNP) | VAF 173/493 reads (35%) | catalogued as rs774261219; called by muse, mutect2, varscan2
- DRD5 | c.738G>A p.T246= | Silent (SNP) | VAF 131/355 reads (37%) | catalogued as COSV58580737; called by muse, mutect2, varscan2
- FBXO43 | c.1305G>A p.K435= | Silent (SNP) | VAF 72/412 reads (17%) | catalogued as COSV104435722; called by muse, mutect2, varscan2
- FDPS | c.1014T>C p.V338= | Silent (SNP) | VAF 293/548 reads (53%) | called by muse, mutect2, varscan2
- FIGNL2 | c.867C>T p.P289= | Silent (SNP) | VAF 515/1095 reads (47%) | catalogued as rs781645879; called by muse, mutect2, varscan2
- FREM2 | c.3207C>A p.I1069= | Silent (SNP) | VAF 207/391 reads (53%) | catalogued as COSV54852503; called by muse, mutect2, varscan2
- GRIN3B | c.555C>T p.G185= | Silent (SNP) | VAF 493/1131 reads (44%) | catalogued as rs748400627; called by muse, mutect2, varscan2
- H4C4 | c.120C>T p.R40= | Silent (SNP) | VAF 223/659 reads (34%) | catalogued as rs756481227; called by muse, mutect2, varscan2
- HEMK1 | c.180C>T p.A60= | Silent (SNP) | VAF 103/295 reads (35%) | called by muse, mutect2, varscan2
- HFM1 | c.3861T>C p.D1287= | Silent (SNP) | VAF 58/197 reads (29%) | called by muse, mutect2, varscan2
- HOXD10 | c.390G>A p.S130= | Silent (SNP) | VAF 123/618 reads (20%) | catalogued as rs1029196107, COSV50899217; called by muse, mutect2, varscan2
- JAK3 | c.2949C>G p.V983= | Silent (SNP) | VAF 134/731 reads (18%) | called by muse, mutect2, varscan2
- LRRTM1 | c.1008C>T p.Y336= | Silent (SNP) | VAF 65/824 reads (8%) | catalogued as COSV54437809, COSV54441028; called by muse, mutect2
- MECOM | c.69C>T p.C23= (on ENST00000468789 / NM_001105078.4; = p.C211= on NM_004991.4) | Silent (SNP) | VAF 99/236 reads (42%) | catalogued as rs188482846, COSV52976360; called by muse, mutect2, varscan2
- NR6A1 | c.51G>A p.S17= | Silent (SNP) | VAF 254/666 reads (38%) | called by muse, mutect2, varscan2
- PCDHA13 | c.1038C>T p.N346= | Silent (SNP) | VAF 83/289 reads (29%) | called by muse, mutect2, varscan2
- PCDHGB1 | c.1728C>T p.R576= | Silent (SNP) | VAF 159/479 reads (33%) | called by muse, mutect2, varscan2
- PPP1R17 | c.426C>T p.I142= | Silent (SNP) | VAF 224/587 reads (38%) | catalogued as rs961740202, COSV59611105; called by muse, mutect2, varscan2
- PRKX | c.109C>T p.L37= | Silent (SNP) | VAF 690/773 reads (89%) | called by muse, mutect2, varscan2
- RAB11FIP5 | c.507G>A p.T169= | Silent (SNP) | VAF 147/516 reads (28%) | catalogued as rs754181912, COSV99242569; called by muse, mutect2, varscan2
- SLC5A9 | c.702C>T p.D234= | Silent (SNP) | VAF 191/510 reads (37%) | catalogued as rs767631035, COSV52585979; called by muse, mutect2, varscan2
- SNX20 | c.684G>A p.P228= | Silent (SNP) | VAF 236/684 reads (35%) | catalogued as rs576966789; called by muse, mutect2, varscan2
- SNX32 | c.102G>A p.V34= | Silent (SNP) | VAF 321/390 reads (82%) | called by muse, mutect2, varscan2
- TRAV38-2DV8 | c.279A>G p.K93= | Silent (SNP) | VAF 125/551 reads (23%) | catalogued as rs747845669; called by muse, mutect2, varscan2
- UNCX | c.720C>T p.G240= | Silent (SNP) | VAF 101/329 reads (31%) | catalogued as COSV100310284; called by muse, mutect2, varscan2
- ZC3H11B | c.1525C>T p.L509= | Silent (SNP) | VAF 142/635 reads (22%) | called by muse, mutect2, varscan2
- CRMP1 | chr4:5892606 C>T | 5'Flank (SNP) | VAF 20/446 reads (4%) | called by muse, mutect2
- CTBP2 | c.58+12848G>A | Intron (SNP) | VAF 225/607 reads (37%) | catalogued as rs200607400, COSV100456379; called by muse, mutect2, varscan2
- ERCC3 | c.1343-280C>T | Intron (SNP) | VAF 147/324 reads (45%) | catalogued as rs980941148; called by muse, mutect2, varscan2
- SLC4A11 | chr20:3238024 T>C | 5'Flank (SNP) | VAF 122/583 reads (21%) | called by muse, mutect2, varscan2
- TMTC3 | c.*2692G>A | 3'UTR (SNP) | VAF 80/400 reads (20%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26675933 T>C | 3'Flank (SNP) | VAF 121/500 reads (24%) | called by muse, mutect2, varscan2
